Somatic mutation profile of tumor specimen TCGA-EK-A2PK-01A (aliquot TCGA-EK-A2PK-01A-11D-A18J-09) from TCGA case TCGA-EK-A2PK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 43.6 years (15,939 days).
Specimen TCGA-EK-A2PK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50d00b52-ce2d-42ce-adaa-844b63545253.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2PK-10A (Blood Derived Normal), aliquot TCGA-EK-A2PK-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d5ca134-4ab7-414d-9949-165b807a1df8

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 9, RNA 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS6 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761621101, COSV66858150; called by muse, mutect2, varscan2
- ARHGAP4 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1557102632; called by muse, mutect2, varscan2
- CDH9 | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs768684659, COSV50281922; called by muse, mutect2, varscan2
- COL11A2 | c.4892C>A p.P1631Q (on ENST00000341947 / NM_080680.3; = p.P1524Q on NM_080679.2) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV100553402; called by muse, mutect2
- HERC6 | c.1192A>G p.T398A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52028133; called by muse, mutect2, varscan2
- KMT5C | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs993179965; called by muse, mutect2, varscan2
- NKD2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as rs754988202; called by muse, mutect2, varscan2
- RANBP2 | c.5904C>G p.F1968L | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV51710116, COSV99311223; called by muse, mutect2, varscan2
- SLCO6A1 | c.1399A>C p.I467L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as COSV101134346, COSV65806334; called by muse, mutect2, varscan2
- APC | c.1375G>C p.D459H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DRP2 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- EIF2B5 | c.531G>T p.R177S (on ENST00000647909; = p.R169S on NM_003907.3) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- ERBIN | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FBN1 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIF14 | c.4222A>G p.S1408G | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- LINGO2 | c.1433G>A p.S478N | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MAP4K3 | c.2570G>C p.R857T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLR2A | c.5231C>T p.T1744I | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- STK11 | c.553_568del p.T185Sfs*97 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- TMEM47 | c.83T>C p.F28S | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ZNF181 | c.1236_1237insCA p.V413Qfs*37 | Frame Shift Ins (INS) | VAF 36/136 reads (26%) | called by mutect2, pindel, varscan2
- ZNF433 | c.1821G>A p.M607I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCB6 | c.729C>A p.G243= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- CHIC2 | c.12C>T p.F4= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs776717900; called by muse, mutect2, varscan2
- DBX2 | c.435G>A p.P145= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs933265525, COSV60336068; called by muse, mutect2, varscan2
- DNAJB11 | c.582C>T p.D194= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs138789127; called by muse, mutect2, varscan2
- GFOD1 | c.765C>A p.A255= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV101014926, COSV64954777; called by muse, mutect2
- HTR1E | c.417C>T p.A139= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs146428063, COSV100541098; called by muse, mutect2, varscan2
- KCNC3 | c.1257C>T p.V419= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs201002118; called by muse, mutect2, varscan2
- PPARD | c.903C>T p.D301= | Silent (SNP) | VAF 52/103 reads (50%) | catalogued as rs771543364; called by muse, mutect2, varscan2
- ZNF836 | c.801C>T p.V267= | Silent (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- FAM27E5 | n.367A>T | RNA (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
